Surgical pathology report (de-identified scan), TCGA case TCGA-VS-A9UJ, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VS-A9UJ-01A (Primary Tumor).

(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Cervix

Cervix biopsy:
Poorly differentiated and invasive squamous cell carcinoma.

ICD O-3
Carcinoma, squamous cell NOS
807013
Site: Cervix NOS
153.9
MD 6/7/14

Source: NCI Genomic Data Commons file 8bdb941a-d15f-4780-994f-e4c4ba6dc520 (TCGA-VS-A9UJ.41D3937F-69E0-4C7F-B38D-A5067B2C3C0B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).